Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AAB4, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AAB4-01A (Primary Tumor).

[page 1 of 3]
Surgery date: Surgical Pathology
REVISED REPORT (Revised information underlined)

DIAGNOSIS:

A. Liver, left lobe nodule, biopsy: Bile duct hemartoma.

B. Lymph node, hepatic artery, biopsy: A single (1) lymph node is negative for tumor.

C. Pancreas, neck margin, excision: Negative for tumor.

D. Body and tail of pancreas, spleen, and portion omentum; distal pancreatectomy: Invasive, well-differentiated (grade 2 of 4) adenocarcinoma involving an area measuring 6.8 x 4.0 x 2.6 cm. The tumor is confined to the pancreas. Extensive perineural invasion is present. Lymphovascular invasion is not identified. The adjacent non-neoplastic pancreatic parenchyma shows chronic pancreatitis. The spleen is uninvolved. A single (of 33) regional lymph node is positive for metastatic adenocarcinoma.
All surgical resection margins are negative for tumor.

With available surgical material, [AJCC pT2 N1]
(7th edition, 2010).

Frozen section histologic interpretation of nodule left lobe liver, hepatic artery lymph node, and neck of pancreas margin performed by:

This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

AMENDMENTS: (Previous Signout Date:

Revision Description: A lymph node was found to be positive for metastatic adenocarcinoma. Diagnosis is changed accordingly.

....Original Diagnosis....

A. Liver, left lobe nodule, biopsy: Bile duct hemartoma.

B. Lymph node, hepatic artery, biopsy: A single (1) lymph node is negative for tumor.

C. Pancreas, neck margin, excision: Negative for tumor.

D. Body and tail of pancreas, spleen, and portion omentum; distal pancreatectomy: Invasive, well-differentiated (grade 2 of 4)

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Overlapping lesion of
pancreas C25.8
J2 5/5/14

[page 2 of 3]
adenocarcinoma involving an area measuring 6.8 x 4.0 x 2.6 cm. The tumor is confined to the pancreas. Extensive perineural invasion is present. Lymphovascular invasion is not identified. The adjacent non-neoplastic pancreatic parenchyma shows chronic pancreatitis. The spleen is uninvolved. Multiple (33) regional lymph nodes are negative for tumor. All surgical resection margins are negative for tumor.

With available surgical material, [AJCC pT2N0] (7th edition, 2010).

Frozen section histologic interpretation of nodule left lobe liver, hepatic artery lymph node, and neck of pancreas margin performed by:

This final pathology report is based on the gross/macrosscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

- A. Received fresh labeled "nodule left lobe liver" is a 0.6 x 0.3 x 0.2 cm aggregate of pale tan soft tissue with a 0.1 x 0.1 x 0.1 cm white plaque within it. All submitted. Grossed by
- B. Received fresh labeled "hepatic artery lymph node" is a 1.8 x 1.6 x 0.9 cm lymph node. All submitted. Grossed by
- C. Received fresh labeled "neck of pancreas margin up" is a 2.8 x 1.7 x 0.8 cm portion of neck of pancreas with orientation. Margin submitted. Grossed by
- D. Received fresh labeled "body and tail of pancreas, spleen, portion of omentum" is a distal pancreatectomy specimen consisting of 7.2 x 4.1 x 3.8 cm portion of pancreas and a 165.0 gram, 10.8 x 7.7 x 5.2 cm spleen and a 14.8 x 11.4 x 2.6 cm portion of omentum. A 6.8 x 4.0 x 2.9 cm firm white fibrous mass is present within the pancreas, 1.1 cm from the proximal pancreatic margin. The mass does not appear to be confined to the pancreas, grossly. The peripancreatic soft tissue is inked. Peripancreatic lymph nodes and splenic hilar lymph nodes are identified. The spleen is grossly unremarkable. Representative sections are submitted. Grossed by

BLOCK SUMMARY:

Part A: Nodule left lobe liver

[page 3 of 3]
1 Nodule Lt lobe liver

Part B: Hepatic artery lymph node

1 Hepatic artery LN 1of2 (B1)

2 Hepatic artery LN 2of2 (B1)

Part C: Neck of pancreas margin

1 Pancreatic neck margin 1

2 Pancreatic neck margin 2

Part D: Body and tail of pancreas, spleen, portion omentum

1 Proximal pancreas

2 Pancreas mass splenic artery

3 Dist pancreatic mass

4 Pancreas w/post soft tissue

5 Dist pancreatic mass 2

6 Spleen

7 Peripancreatic LN 3(D1)

8 Peripancreatic LN 5(D2)

9 Peripancreatic LN 5(D3)

10 Peripancreatic LN 5(D4)

11 Peripancreatic LN 5(D5)

12 Peripancreatic LN 4(D6)

13 Peripancreatic LN 1(D7)

14 Peripancreatic LN 1(D8)

15 Peripancreatic LN 2(D9)

Source: NCI Genomic Data Commons file e4cb7465-b72f-405b-b18e-f3aa22fe29ef (TCGA-2J-AAB4.A59BDECC-6076-4035-A359-EED94BBF3C95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).